Somatic mutation profile of tumor specimen ALCH-B1OY-TTP1-A (aliquot ALCH-B1OY-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1OY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.0 years (20,079 days).
Specimen ALCH-B1OY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 703be2cd-cb13-4b1a-bfc3-9be5239776fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OY-NB1-A (Blood Derived Normal), aliquot ALCH-B1OY-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ece8de1a-d6aa-45f7-9e49-8d4dd50bc56f

The open-access MAF lists 252 somatic variants for this specimen: 175 protein-altering or splice-affecting, 55 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 55, Nonsense Mutation 11, RNA 9, Splice Site 7, Intron 6, 3'UTR 4, Splice Region 2, 5'Flank 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1923A>C p.K641N (on ENST00000288602 / NM_001374244.1; = p.K601N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs121913365, COSV56057324, COSV56058093, COSV56255469; ClinVar: likely pathogenic; called by muse, mutect2
- AC011455.2 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1334426276; called by muse, mutect2
- AKNAD1 | c.1664+1G>T p.X555_splice | Splice Site (SNP) | VAF 9/94 reads (10%) | catalogued as rs759160775, COSV62205152; called by muse, mutect2
- BRINP2 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 43/619 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV64176075; called by muse, mutect2
- BRINP2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64180248; called by muse, mutect2
- CACNA2D3 | c.971G>T p.R324M | Missense Mutation (SNP) | VAF 17/357 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99876871; called by muse, mutect2
- CDH10 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 23/502 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52570069, COSV52589927; called by muse, mutect2
- CFH | c.428-1G>T p.X143_splice | Splice Site (SNP) | VAF 8/140 reads (6%) | catalogued as COSV62776053; called by muse, mutect2
- CSN2 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 20/710 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV61992630; called by muse, mutect2
- CTNNA2 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 8/166 reads (5%) | catalogued as COSV58191612; called by muse, mutect2
- FER1L6 | c.5468A>T p.K1823M | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV67549528; called by muse, mutect2
- GIMAP4 | c.620G>C p.G207A | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1436248227; called by muse, mutect2
- GPAT2 | c.2013C>A p.D671E | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758198594, COSV64003895; called by muse, mutect2
- IL16 | c.676-2A>T p.X226_splice | Splice Site (SNP) | VAF 22/484 reads (5%) | catalogued as COSV57262687; called by muse, mutect2
- IRS2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 58/1016 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1370291086, COSV65476975; called by muse, mutect2
- ITGA8 | c.1445+2T>G p.X482_splice | Splice Site (SNP) | VAF 16/362 reads (4%) | catalogued as COSV100959222; called by muse, mutect2
- KCNC2 | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV54374431; called by muse, mutect2
- KIAA2012 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184590177; called by muse, mutect2
- KIF3C | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 21/400 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV53100605; called by muse, mutect2
- LRP1B | c.3289C>A p.H1097N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV101257735; called by muse, mutect2
- LRRK1 | c.3914G>T p.R1305L | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99437310, COSV99440520; called by muse, mutect2
- MYO15A | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1213311182; called by muse, mutect2
- NPSR1 | c.866C>A p.P289Q | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62206211; called by muse, mutect2
- OR2G2 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100189754; called by muse, mutect2
- OR6P1 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 48/816 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58110569; called by muse, mutect2
- PADI3 | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV64934678; called by muse, mutect2
- PKP4 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 22/455 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777153780; called by muse, mutect2
- PLCD1 | c.1202T>C p.M401T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs752099937; called by muse, mutect2
- PROX1 | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 6/142 reads (4%) | catalogued as COSV54778350; called by muse, mutect2
- PRUNE2 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100944378; called by muse, mutect2
- PSG2 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV68885073; called by muse, mutect2
- RELN | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 14/398 reads (4%) | catalogued as COSV59031180; called by muse, mutect2
- RTL4 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV61207672; called by muse, mutect2
- SERPINA7 | c.495C>A p.N165K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs369350028; called by muse, mutect2, varscan2
- SLC12A7 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444780464; called by muse, mutect2
- SLC30A10 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 32/589 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63074531; called by muse, mutect2
- SLC6A16 | c.2089A>G p.M697V | Missense Mutation (SNP) | VAF 18/510 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1367952407; called by muse, mutect2
- SMO | c.1290G>C p.K430N | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99976830; called by muse, mutect2
- SPEF1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757143804; called by muse, mutect2
- TERT | c.1573+6G>T | Splice Region (SNP) | VAF 20/334 reads (6%) | catalogued as rs1561213199; called by muse, mutect2
- YY1AP1 | c.1748G>T p.R583M (on ENST00000295566 / NM_139118.2; = p.R526M on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/457 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV55125229, COSV99803804; called by muse, mutect2
- ZNF599 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 16/189 reads (8%) | catalogued as COSV100251153; called by muse, mutect2
- ZNF665 | c.893A>T p.K298M (on ENST00000600412; = p.K363M on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as COSV67217783; called by muse, mutect2
- ZNF804B | c.1594C>A p.Q532K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV60845674; called by muse, mutect2
- ZPBP | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 14/354 reads (4%) | catalogued as COSV50422796; called by muse, mutect2
- ABCC2 | c.3614+1G>C p.X1205_splice | Splice Site (SNP) | VAF 19/650 reads (3%) | called by muse, mutect2
- AC004922.1 | c.1315A>T p.N439Y | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.783); called by muse, mutect2
- AC131160.1 | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ACAN | c.1186A>T p.S396C | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- AMER1 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ANK3 | c.8182G>C p.A2728P | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- ANKRD36 | c.1916T>A p.M639K | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.153); called by muse, mutect2
- APOA5 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ARHGEF33 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2
- ARMC7 | c.315C>G p.N105K | Missense Mutation (SNP) | VAF 31/329 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ATP2B2 | c.2594C>A p.S865Y (on ENST00000352432; = p.S831Y on NM_001683.5) | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BTN2A1 | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.034); called by muse, mutect2
- BTN2A2 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 28/401 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2
- C1QA | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 20/450 reads (4%) | called by muse, mutect2
- CACNA2D4 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.11); called by muse, mutect2
- CADM1 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD163 | c.2683T>A p.C895S | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CELA2B | c.764T>A p.V255D | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELF2 | c.1072G>T p.A358S (on ENST00000416382 / NM_001025077.3; = p.A365S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/738 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, mutect2
- CNGB3 | c.1217T>A p.I406N | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CYP19A1 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); called by muse, mutect2
- DCAF12L1 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- DLGAP2 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 32/567 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- DROSHA | c.2395A>G p.K799E | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- DSCAML1 | c.5198A>G p.K1733R (on ENST00000321322; = p.K1673R on NM_020693.4) | Missense Mutation (SNP) | VAF 36/492 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- ERLIN2 | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 105/989 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- EXO1 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 27/488 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- EYA4 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 26/758 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- FAM180B | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FANCE | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- FAT3 | c.3813A>T p.R1271S | Missense Mutation (SNP) | VAF 20/417 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.805); called by muse, mutect2
- FGD5 | c.2812G>T p.A938S | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2
- GATAD2B | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 18/465 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); called by muse, mutect2
- GINS1 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 36/475 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- GINS1 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 36/485 reads (7%) | called by muse, mutect2
- GNPAT | c.1811T>A p.V604D | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- GPAA1 | c.1727A>T p.E576V | Missense Mutation (SNP) | VAF 25/538 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2
- H3C8 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 38/564 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.148); called by muse, mutect2
- H6PD | c.1093A>G p.R365G | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2
- HERC2 | c.8938-2A>T p.X2980_splice | Splice Site (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- HLCS | c.1770G>A p.M590I | Missense Mutation (SNP) | VAF 20/457 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2
- HMCN1 | c.6676C>T p.P2226S | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IARS1 | c.1717G>T p.V573L | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGF1R | c.2538C>G p.N846K | Missense Mutation (SNP) | VAF 42/567 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- IGHM | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 35/826 reads (4%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.578); called by muse, mutect2
- IGHV6-1 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- IGKV1D-33 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/340 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.154); called by muse, mutect2
- IGKV6D-41 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL7R | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.018); called by muse, mutect2
- KCNK2 | c.1124A>T p.Q375L (on ENST00000444842 / NM_001017425.3; = p.Q360L on NM_014217.4) | Missense Mutation (SNP) | VAF 23/508 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.254); called by muse, mutect2
- KCNQ4 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- KCTD20 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIAA1841 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- KLHDC9 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL42 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- LCT | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 52/784 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2
- LGSN | c.1215A>G p.I405M | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- LPAR5 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- MAGEB6B | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP6 | c.1878G>T p.K626N | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.368); called by muse, mutect2
- MUC16 | c.22682C>A p.T7561N | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); called by muse, mutect2
- MXRA5 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- N4BP1 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NBAS | c.2207G>T p.S736I | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NELL1 | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NHSL2 | c.365C>A p.P122H (on ENST00000510661; = p.P488H on NM_001013627.2) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NUP210 | c.3377G>T p.G1126V | Missense Mutation (SNP) | VAF 52/679 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP210 | c.1434C>A p.A478= | Splice Region (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- OR13J1 | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- OR2T34 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- OR4K13 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2
- OR5AU1 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PCARE | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2
- PCDHA5 | c.2302C>G p.L768V | Missense Mutation (SNP) | VAF 34/561 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PCDHGB4 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); called by muse, mutect2
- PEG3 | c.3587G>A p.C1196Y | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PEPD | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PEX5L | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 44/477 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIP | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2
- PLEKHH2 | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PLEKHO1 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.54); called by muse, mutect2
- POTED | c.386T>A p.M129K | Missense Mutation (SNP) | VAF 29/526 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2
- PRKCG | c.1856G>A p.W619* | Nonsense Mutation (SNP) | VAF 23/768 reads (3%) | called by muse, mutect2
- PRKD1 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 24/443 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- PSG3 | c.1047C>G p.N349K | Missense Mutation (SNP) | VAF 12/406 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- PTH1R | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 12/389 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2
- PUM2 | c.2366T>A p.L789Q | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- RNF122 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2
- RUNDC3B | c.843A>C p.E281D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RYR2 | c.6289G>T p.G2097C | Missense Mutation (SNP) | VAF 23/571 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- RYR2 | c.9024C>G p.F3008L | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- RYR2 | c.14393A>T p.D4798V | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- S1PR1 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN1A | c.3724A>G p.I1242V (on ENST00000303395 / NM_001202435.3; = p.I1231V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2
- SEMA5B | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SERINC3 | c.396-2A>G p.X132_splice | Splice Site (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- SH3BP4 | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIDT1 | c.123C>A p.D41E | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2
- SLC17A3 | c.1225C>A p.Q409K | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SLC20A1 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 36/584 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.047); called by muse, mutect2
- SLC35G2 | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC5A7 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SOX30 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.431); called by muse, mutect2
- SPATA31A1 | c.1580C>G p.A527G | Missense Mutation (SNP) | VAF 30/902 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2
- SPATC1 | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by mutect2, varscan2
- SPEG | c.6073C>A p.P2025T | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- STYXL2 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SVEP1 | c.6163G>T p.D2055Y | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2
- TIAM1 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 20/479 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- TNR | c.2131G>T p.G711C | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOP2B | c.4753A>T p.I1585F (on ENST00000264331 / NM_001330700.2; = p.I1580F on NM_001068.3) | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.339); called by muse, mutect2
- TRAFD1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2
- TRAPPC5 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.186); called by muse, mutect2
- TRIM32 | c.122A>T p.H41L | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTC6 | c.608C>T p.A203V (on ENST00000267368; = p.A1569V on NM_001310135.3) | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTLL8 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 20/614 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TTN | c.3505G>T p.A1169S (on ENST00000591111; = p.A1123S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/343 reads (6%) | PolyPhen benign (0.254); called by muse, mutect2
- VCAN | c.8954G>A p.G2985E | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.131); called by muse, mutect2
- VGLL2 | c.663C>A p.Y221* | Nonsense Mutation (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- VNN1 | c.1025T>A p.F342Y | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.163); called by muse, mutect2
- VSIG8 | c.362C>G p.T121R | Missense Mutation (SNP) | VAF 38/873 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- XDH | c.3781G>A p.G1261R | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- XIRP2 | c.1316T>G p.V439G (on ENST00000628543; = p.V614G on NM_152381.6) | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX4 | c.7129G>C p.A2377P | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- ZNF681 | c.1182C>G p.Y394* | Nonsense Mutation (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- ZNF711 | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF735 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF804A | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 27/683 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF813 | c.947G>T p.R316I | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ZP4 | c.1240C>A p.H414N | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2
- ABCC12 | c.2490C>A p.P830= | Silent (SNP) | VAF 29/479 reads (6%) | called by muse, mutect2
- ADAMTS12 | c.3501G>A p.E1167= | Silent (SNP) | VAF 7/176 reads (4%) | catalogued as COSV100710426; called by muse, mutect2
- AGBL1 | c.2037C>A p.P679= | Silent (SNP) | VAF 15/496 reads (3%) | called by muse, mutect2
- ALKAL1 | c.373C>T p.L125= | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- ARHGEF6 | c.564C>T p.Y188= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as rs1458824176, COSV51688508, COSV51693828; called by muse, mutect2
- BMP1 | c.1815G>T p.P605= | Silent (SNP) | VAF 51/614 reads (8%) | called by muse, mutect2
- COQ6 | c.978C>T p.V326= | Silent (SNP) | VAF 44/1051 reads (4%) | called by muse, mutect2
- CRB2 | c.204C>A p.P68= | Silent (SNP) | VAF 13/306 reads (4%) | catalogued as rs948027426; called by muse, mutect2
- CUX2 | c.927G>A p.E309= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- ERCC3 | c.1218C>T p.A406= | Silent (SNP) | VAF 32/900 reads (4%) | called by muse, mutect2
- F7 | c.189G>T p.A63= | Silent (SNP) | VAF 33/598 reads (6%) | called by muse, mutect2
- FBN2 | c.5667C>A p.A1889= | Silent (SNP) | VAF 30/542 reads (6%) | catalogued as COSV52496972; called by muse, mutect2
- FMNL3 | c.732C>A p.V244= | Silent (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- GRM8 | c.1176G>T p.R392= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- HOXC11 | c.690C>A p.P230= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV54532100; called by muse, mutect2
- HRG | c.1554T>C p.F518= | Silent (SNP) | VAF 11/301 reads (4%) | called by muse, mutect2
- IFNGR2 | c.129A>T p.A43= | Silent (SNP) | VAF 48/878 reads (5%) | called by muse, mutect2
- ITLN2 | c.657A>T p.I219= | Silent (SNP) | VAF 18/317 reads (6%) | called by muse, mutect2
- KCNA6 | c.465C>A p.P155= | Silent (SNP) | VAF 36/694 reads (5%) | catalogued as COSV54974179; called by muse, mutect2
- KCNK3 | c.471C>T p.A157= | Silent (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- LRRC72 | c.15G>C p.P5= | Silent (SNP) | VAF 16/460 reads (3%) | catalogued as COSV66127013; called by muse, mutect2
- MAPK8IP1 | c.1182G>T p.V394= | Silent (SNP) | VAF 32/586 reads (5%) | called by muse, mutect2
- MAPT | c.1494G>A p.L498= (on ENST00000262410 / NM_001377265.1; = p.L423= on NM_016835.4) | Silent (SNP) | VAF 13/247 reads (5%) | catalogued as rs771166056, COSV52237381; called by muse, mutect2
- MAS1L | c.348C>A p.V116= | Silent (SNP) | VAF 24/484 reads (5%) | catalogued as COSV65808999; called by muse, mutect2
- MMADHC | c.411A>T p.A137= | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as COSV100307187; called by muse, mutect2
- NES | c.1401A>T p.A467= | Silent (SNP) | VAF 20/312 reads (6%) | called by muse, mutect2
- NLRP10 | c.978C>T p.S326= | Silent (SNP) | VAF 30/522 reads (6%) | catalogued as COSV60780853, COSV60783293; called by muse, mutect2
- NPAS3 | c.1281C>A p.I427= (on ENST00000356141 / NM_001164749.2; = p.I395= on NM_022123.3) | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV60852235; called by muse, mutect2
- OCA2 | c.1072C>T p.L358= | Silent (SNP) | VAF 24/824 reads (3%) | called by muse, mutect2
- OR9Q2 | c.387C>A p.P129= | Silent (SNP) | VAF 12/363 reads (3%) | catalogued as COSV61112775; called by muse, mutect2
- OTOGL | c.2793T>A p.V931= (on ENST00000547103; = p.V922= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- PASD1 | c.96C>T p.Y32= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- PKP2 | c.726G>T p.T242= | Silent (SNP) | VAF 34/779 reads (4%) | called by muse, mutect2
- PLAAT3 | c.306G>A p.Q102= | Silent (SNP) | VAF 26/584 reads (4%) | called by muse, mutect2
- PRF1 | c.48C>G p.P16= | Silent (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- RANBP2 | c.2529A>T p.T843= | Silent (SNP) | VAF 44/908 reads (5%) | called by muse, mutect2
- RASGEF1A | c.159G>A p.L53= | Silent (SNP) | VAF 22/376 reads (6%) | called by muse, mutect2
- RDH14 | c.798A>T p.P266= | Silent (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- RHAG | c.822T>C p.N274= | Silent (SNP) | VAF 32/610 reads (5%) | called by muse, mutect2
- RPS6KA4 | c.699G>T p.T233= | Silent (SNP) | VAF 17/222 reads (8%) | catalogued as COSV99590264; called by muse, mutect2
- RTL3 | c.1137C>A p.A379= | Silent (SNP) | VAF 26/362 reads (7%) | catalogued as COSV58185369; called by muse, mutect2
- RYR2 | c.6288G>T p.G2096= | Silent (SNP) | VAF 22/567 reads (4%) | catalogued as COSV63672427; called by muse, mutect2
- SLC38A7 | c.1212C>T p.C404= | Silent (SNP) | VAF 12/360 reads (3%) | called by muse, mutect2
- SLC6A20 | c.138C>T p.P46= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as rs1012557544; called by muse, mutect2
- SLCO1B1 | c.1827A>T p.T609= | Silent (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- TARS3 | c.1080C>A p.S360= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- TAS2R5 | c.663G>T p.L221= | Silent (SNP) | VAF 20/287 reads (7%) | catalogued as COSV56095459; called by muse, mutect2
- TLR7 | c.180T>G p.P60= | Silent (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- TMEM132C | c.1644G>T p.V548= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- TSHR | c.1791C>A p.V597= | Silent (SNP) | VAF 26/734 reads (4%) | called by muse, mutect2
- TTC28 | c.4044G>A p.R1348= | Silent (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- TTN | c.69918C>A p.R23306= (on ENST00000591111; = p.R15882= on NM_003319.4) | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- TYK2 | c.1860G>A p.K620= | Silent (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- UNC13A | c.115C>A p.R39= | Silent (SNP) | VAF 25/461 reads (5%) | catalogued as COSV53193107; called by muse, mutect2
- ZBTB39 | c.1995C>G p.V665= | Silent (SNP) | VAF 71/504 reads (14%) | called by muse, mutect2, varscan2
- AC011525.1 | n.836A>T | RNA (SNP) | VAF 23/498 reads (5%) | called by muse, mutect2
- AC011525.1 | n.835C>T | RNA (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- AC016705.2 | n.119G>T | RNA (SNP) | VAF 14/311 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73848207 C>A | 5'Flank (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- AP002008.2 | n.1972C>A | RNA (SNP) | VAF 25/260 reads (10%) | called by muse, mutect2
- AURKA | c.1029+32C>A | Intron (SNP) | VAF 30/629 reads (5%) | called by muse, mutect2
- CEP41 | c.*2092G>A | 3'UTR (SNP) | VAF 9/80 reads (11%) | catalogued as rs1477602850; called by muse, mutect2, varscan2
- FUNDC2P2 | n.312C>A | RNA (SNP) | VAF 38/802 reads (5%) | catalogued as rs568023347; called by muse, mutect2
- FUS | c.1292+43G>C | Intron (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- IFT57 | c.494+42A>T | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- IGHV1-18 | c.-17G>T | 5'UTR (SNP) | VAF 26/422 reads (6%) | called by muse, mutect2
- KIR3DX1 | n.585A>G | RNA (SNP) | VAF 13/343 reads (4%) | called by muse, mutect2
- KLC2 | c.*295C>T | 3'UTR (SNP) | VAF 15/327 reads (5%) | called by muse, mutect2
- LINC01559 | n.525A>T | RNA (SNP) | VAF 32/574 reads (6%) | called by muse, mutect2
- MTHFD2L | chr4:74158052 C>A | 5'Flank (SNP) | VAF 12/215 reads (6%) | called by muse, mutect2
- NAMPTP1 | n.307G>T | RNA (SNP) | VAF 27/766 reads (4%) | called by muse, mutect2
- OR2M1P | n.346G>T | RNA (SNP) | VAF 20/492 reads (4%) | called by muse, mutect2
- PDGFRA | c.1787-47G>C | Intron (SNP) | VAF 20/454 reads (4%) | called by muse, mutect2
- PEX19 | c.*2178C>A | 3'UTR (SNP) | VAF 23/468 reads (5%) | called by muse, mutect2
- RASGRP2 | c.*6+32C>A | Intron (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- SETD5 | c.72-452G>T | Intron (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- XIAP | c.*4857A>T | 3'UTR (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
